Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-B0GI, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-B0GI-TTP1-A (Primary Tumor).

[page 1 of 25]
ED to Hosp-Admission
MRNDescription
Encounter

Order

Surgical Pathology Request

Surgical Pathology Request

Collected: Status: Final result Visible to patient: Yes
+0

Order

Narrative

FINAL DIAGNOSIS

SYNOPTIC REPORT FOR THE ADENOCARCINOMA OF THE CECUM:

Pathologic Stage (AJCC 7th edition): pT3 N2b M1b

Number of Regional Lymph Nodes Examined: 24 (part G)

Number of Lymph Nodes Involved by Carcinoma: 12 (part G)

Distant Metastasis: Peritoneum, bilateral ovaries, left fallopian tube, uterus, small intestine, omentum

Margins: Tumor present in a lymph node at the mesenteric margin near cecum; tumor present at proximal margin of distal small bowel resection (part H); proximal and distal margins (part G) are free of tumor

Tumor Site: Cecum

Tumor Size: 4 x 2 x 1 cm

Macroscopic Tumor Perforation: Not identified

Histologic Type: Adenocarcinoma

Histologic Grade: Low-grade (well-differentiated to moderately differentiated)

Intratumoral Lymphocytic Response (tumor-infiltrating lymphocytes): None

Peritumor Lymphocytic Response (Crohn-like response): None

Microscopic Tumor Extension: Tumor invades into the subserosal adipose tissue

Treatment Effect: No prior treatment

Lymph-Vascular Invasion: Present, extensive

Perineural Invasion: Not identified

Tumor Deposits (discontinuous extramural extension): Present, multiple

There is no loss of expression in tumor nuclei of the mismatch repair proteins MLH1, MSH2, MSH6, and PMS2 by immunohistochemical stain tests.

No loss of nuclear expression of mismatch repair proteins implies a low probability of a microsatellite instability high tumor. Positive controls stain appropriately.

The results of molecular testing to be reported separately.

A) Peritoneal lesion (biopsy):

- Metastatic cecal adenocarcinoma in fibroadipose tissue.

B) Mesenteric nodule (biopsy):

[page 2 of 25]
Metastatic cecal adenocarcinoma in fibroadipose tissue.

C) Left adnexa (excision):

- Metastatic cecal adenocarcinoma replacing the left ovary.
- Portion of fallopian tube.

D) Pericolonic tissue (biopsy):

- Fibroadipose tissue, negative for carcinoma.

E) Uterus, cervix, bilateral fallopian tubes, and right ovary (total abdominal hysterectomy, bilateral salpingectomy, and right oophorectomy):

- Metastatic cecal adenocarcinoma to right ovary, left fallopian tube and as a single, minute subserosal uterine deposit.
- Endometrial polyp (6.5 cm).
- Uterine leiomyomata.

F) Mesenteric nodule (biopsy):

- Metastatic cecal adenocarcinoma in fibroadipose tissue.

G) Large intestine, cecum and ascending colon (right hemicolectomy):

- Adenocarcinoma of the cecum (see synoptic report above).
- Metastatic cecal adenocarcinoma to the omentum.
- Appendix with fibrous obliteration of the lumen.

H) Distal small bowel (segmental resection):

- Metastatic cecal adenocarcinoma as multiple subserosal deposits.
- Proximal margin of resection involved by metastatic cecal adenocarcinoma.
- Distal and mesenteric margins are free of tumor.
- Acute serositis.

I) Omentum (omentectomy):

- Metastatic cecal adenocarcinoma, multifocal, in omental tissue.

COMMENT

Immunohistochemical stains for keratin 7, keratin 20, CDX-2, and PAX8 are performed on the left adnexa tumor (part C) and the cecal tumor (part G). The tumor at both sites shows an identical immunophenotype: Strong positive for keratin 20, patchy positive for keratin 7, CDX-2 positive, and PAX8 negative.

CLINICAL HISTORY

69-year-old female who presented to the ED last night with worsening abdominal pain and emesis after one month history of abdominal distention. NG placed with improved. Concern for malignancy. Known colon mass suspicious for CA.

GROSS DESCRIPTION

Received fresh are three specimens labeled

[page 3 of 25]
A) Labeled "peritoneal lesion" and consists of a 0.7 x 0.5 x 0.4 cm tan-pink soft tissue fragment. Specimen is entirely submitted for frozen section analysis, with the remnant as [REDACTED].

B) Labeled "mesenteric nodule" and consists of 2 tan-red soft tissue fragments, 0.6 x 0.4 x 0.3 cm in aggregate. Specimen is entirely submitted for frozen section analysis, with the remnant as [REDACTED].

C) Labeled "left adnexa" and consists of a 237 g, 10.4 x 8.9 x 5.8 cm pink-red-tan, encapsulated, nodular to lobulated soft tissue fragment. Sectioning reveals tan-pink-red, gritty to friable to necrotic predominantly solid cut surfaces. Cystic component (approximately 20%) discharges thin mucinous contents from within smooth walled cystic spaces that range from 0.3-1.8 cm in greatest dimension. Representative sections submitted for frozen section analysis, with the remnant as [REDACTED]. Additional representative sections are submitted as [REDACTED]. Digital photograph taken.
[REDACTED]

D) Received fresh for intraoperative consultation, labeled [REDACTED] and further designated "pericolonic biopsy," is a 0.9 x 0.3 x 0.2 cm tan-yellow soft tissue. The specimen is submitted entirely for frozen section analysis and resubmitted as [REDACTED].

E) Received fresh for intraoperative consultation, labeled [REDACTED] and further designated "uterus, cervix, fallopian tubes, right ovary," is a hysterectomy, bilateral salpingectomy, and right oophorectomy specimen. The uterus (432 g, 15.5 cm superior to inferior, 8.2 cm cornu to cornu, 7.8 cm anterior to posterior) has a tan-pink, smooth, glistening serosal surface. The ectocervix is tan-white, smooth, and glistening. The cervical os (0.1 cm) is pinpoint and not probe patent. The anterior cervix is inked blue, and the posterior cervix is inked black. The uterus is bivalved revealing the endocervix (2.9 cm in length) to be lined by tan-pink, smooth, and glistening mucosa. The triangular endometrial cavity (6 x 3.4 cm) demonstrates a tan-pink to red polypoid mass (6.5 x 5.7 x 1 cm) predominantly involving the posterior endometrium with extension into the left anterior endometrium. Serial sectioning reveals no definite myometrial invasion. The uninvolved endometrium (0.2 cm thick) is tan-pink. The myometrium (3.5 cm thick) is tan-pink and trabeculated. Numerous circumscribed, white, firm, whorled nodules (1 to 4 cm in greatest diameter) are identified within the anterior and posterior myometrium. Hemorrhage and necrosis are not identified within these nodules. The right fallopian tube (3.5 cm in length x 0.6 cm in diameter) has an unremarkable tan-pink fimbriated end. The serosa is tan-gray and without discrete lesion. The lumen is pinpoint. The right ovary (3.2 x 1.9 x 1.9 cm) has a tan to pink, smooth, glistening external surface. The fimbriated end is adhered to the ovary. Serial sectioning reveals one unilocular, smooth walled cyst within the ovary (1 x 0.9 x 0.9 cm). The remainder of the ovarian cut surface is tan-pink to white. The left fallopian tube (3.8 cm in length x 0.8 cm in diameter) does not demonstrate a fimbriated end. The serosa is tan-pink, smooth, and glistening. The lumen is pinpoint. Representative sections are submitted as follows:

[REDACTED] Endometrial polyp, frozen section remnant

[REDACTED]

[page 4 of 25]
- (E2) Anterior endo- and ectocervix
- (E3) Posterior endo- and ectocervix
- (E4) Anterior lower uterine segment
- (E5) Posterior lower uterine segment
- (E6-E7) Anterior endomyometrium, full thickness, with polyp
- (E8-E9) Posterior endomyometrium, full thickness, with polyp
- (E10-E11) Anterior endomyometrium with polyp
- (E12-E13) Posterior endomyometrium with polyp
- (E14) Anterior myometrium with circumscribed nodule, two sections
- (E15) Posterior myometrium with circumscribed nodule, two sections
- (E16) Right ovarian cyst, submitted entirely
- (E17-E18) Right ovary with adherent fimbriated end of fallopian tube
- (E19) Right fallopian tube, remainder of fimbriated end and additional cross-section
- (E20) Left fallopian tube, three cross-sections

F) Designated "mesenteric nodule, suspect colon and ovarian cancer," is a tan-yellow soft tissue (0.3 x 0.2 x 0.2 cm). The specimen is submitted entirely in (F1).

G) Designated "colon, two pieces, #1 cecum, ascending, #2 ascending, transverse, stitches mark distal" is a right hemicolectomy specimen (15.5 x 13 x 5 cm) consisting of terminal ileum (6.2 cm in length x 3.2 cm in diameter), cecum (13 cm in length x 4-7 cm in diameter), appendix (6 cm in length x 0.6 cm in diameter) and mesentery (14 x 7 x 1.5 cm). There is a second length of bowel (15 cm in length x 3 cm in diameter) with attached mesentery and omentum (15 x 4 x 1 cm). The serosa of the terminal ileum is tan-pink, smooth, and glistening. The serosa of the cecum is tan-pink with an area of tan nodularity adjacent to an area of puckering near the junction of the ileum and cecum. The mesentery also demonstrates two areas of puckering subjacent to which are firm, white, irregular nodules (0.8 to 1.2 cm in greatest diameter). The specimen is opened longitudinally revealing an ulcerating, circumferential cecal mass (4 x 2 x 1 cm) corresponding to the area of serosal nodularity and puckering. The mass is 2.5 cm inferior to the ileocecal valve, 7 cm from the proximal margin, and 10 cm from the mesenteric margin. The mass is invasive through the muscularis propria into the surrounding adipose tissue. The mass abuts the closest radial margin (black ink). The uninvolved ileal and colonic mucosa is tan with the usual folds. The appendix is unremarkable. The second portion of bowel demonstrates a 1.1 x 0.9 x 0.9 cm circumscribed firm white nodule within the omentum that is 1 cm from the mesenteric margin. The serosal surface is tan-pink with areas of adhesion. The bowel is opened longitudinally revealing tan-pink mucosa with the usual folds. The pericolic adipose tissue of both portions of bowel is searched and 19 lymph nodes are identified ranging in diameter from 0.4 to 0.9 cm. Representative sections are submitted as follows:

- (G1) Ileal/cecal mesenteric margin, en face
- (G2) Proximal margin, en face
- (G3) Distal margin, en face
- (G4) Mesenteric nodule #1, two sections
- (G5) Mass to closest radial margin
- (G6-G8) Mass with invasion into surrounding adipose tissue
- (G9) Mass to uninvolved colonic mucosa
- (G10) Ascending/transverse colon mesenteric margin, en face

[page 5 of 25]
- (G11) Omental nodule, two sections
- (G12) Appendix
- (G13) Mesenteric nodule #2
- (G14) One lymph node, bisected
- (G15) Five lymph nodes
- (G16) Five lymph nodes
- (G17) Five lymph nodes
- (G18) Three lymph nodes
- (G19) Uninvolved ileum and cecum
- (G20) Uninvolved ascending/transverse colon

H) Designated "distal small bowel, long stitch marks distal, short stitches mark mesenteric masses," is a partial small bowel resection specimen consisting of small bowel (55 cm in length x 2 to 3.5 cm in diameter) and attached mesentery (5 cm in length x 0.5 cm in thickness). The serosal surfaces of the small bowel are tan-pink, smooth and glistening. The mesentery contains two stitches designating firm white nodules (0.3 to 0.6 cm in greatest diameter). Two additional stitches within the bowel serosa designate two subserosal nodules (0.4 to 0.6 cm in greatest diameter). Sectioning reveals these nodules to be contained to the adipose tissue and not invasive into the muscular wall of the small intestine. The small bowel has tan unremarkable mucosa with the usual folds. Representative sections are submitted as follows:

- (H1) Proximal margin, en face
- (H2) Distal margin, en face
- (H3-H4) Mesenteric nodules
- (H5-H7) Small bowel with submural nodules
- (H8) Six candidate lymph nodes
- (H9) Uninvolved small bowel

I) Designated "omentum," is a 26 x 10 x 1 cm portion of omentum with multiple firm, tan, irregular nodules (up to 1 cm in greatest diameter) scattered throughout. The uninvolved adipose tissue is yellow and lobulated. Two representative sections of the nodules are submitted in (I1).

INTRAOPERATIVE DIAGNOSIS

- A (peritoneal lesion): Positive for adenocarcinoma
- B (mesenteric nodule): Positive for adenocarcinoma
- C: Positive for adenocarcinoma
- D: Negative for carcinoma
- E: Large endometrial polyp, negative for carcinoma on one representative section

Intra-Operative Diagnosis Reviewed and Interpreted By:

[page 6 of 25]
'I certify that (1) all services on this form were rendered and are hereby approved for billing, (2) all specimens/slides have been examined / reviewed, (3) the medical record has been documented for these services, and (4) the rendering of the services and the documentation in the medical record are in accordance with [REDACTED] guidelines.'

Final Diagnosis Reviewed and Interpreted by:

ELECTRONICALLY SIGNED

Pathologist - [REDACTED]

Date:

+2

Surgical Pathology

"I certify that (1) all services on this form were rendered and are hereby approved for billing, (2) all specimens/slides have been examined / reviewed, (3) the medical record has been documented for these services, and (4) the rendering of the services and the documentation in the medical record are in accordance with [REDACTED] guidelines."

+0

+2

Specimen Collected
AM

Last Resulted
AM

Comment

Comment

Order

Ordered by an unspecified provider

Collection Information

Specimen ID: [REDACTED]

Resulting Agency [REDACTED]

Surgical Pathology Request (Order [REDACTED])

+0

Result Information

[page 7 of 25]
Resulted Date/Time

Final result (Collected: [REDACTED] +0

Surgical Pathology Request

+2

Ordering Physician

69 y.o. multigravida
Provider Not In System

Surgery Report

Lab Printout

Open Hard Copy Result Report (Order [REDACTED] Surgical Pathology Request)

Order Report

View Order Information

Description: Female DOB: [REDACTED] Department: [REDACTED]
Encounter #: [REDACTED]

Lab Collection Information

Collected: [REDACTED] +0

Lab IDs

Specimen # [REDACTED]

Surgical Pathology Request (Order [REDACTED])

Lab

Date and Time: [REDACTED] Department: Surgical Specialties Unit Ordering User: (auto-released)
Authorizing: [REDACTED]

Diagnoses

	Codes	Comments
Pelvic varices - Primary	I86.2	
Small bowel obstruction (HC code)	K56.69	
Colon stricture (HC code)	K56.69	
Gastroesophageal reflux disease, esophagitis presence not specified	K21.9	
Gastric distention	K31.89	
Colon cancer metastasized to multiple sites (HC code)	C18.9	
Adenocarcinoma of cecum (HC code)	C18.0	
Intestinal obstruction, unspecified intestinal obstruction type (HC code)	K56.60	

[page 8 of 25]
Order Information

Order Date/Time	Release Date/Time	Start Date/Time	End Date/Time
[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]

Comments	+0	+0	+0	+0
Ordered by an unspecified provider				

Order Details

Frequency	Duration	Priority	Order Class
ONCE	1 occurrence	Routine	Normal

Provider Information

Collection Information

Specimen	Collected	Received	Resulting Agency
[REDACTED]	+0	+0	[REDACTED]

Order Report

[View Order Information](#)

There are no specimens.

Reprint Requisitions

Surgical Pathology Request (Order # [REDACTED]) +0

Order Routing Information

[View Order Routing Information](#)

[page 9 of 25]
Encounter # [REDACTED] Department [REDACTED] Admission [REDACTED]

Patient Information

Patient Name

Sex

DOB

SSN

Op Note signed by [REDACTED]

Record

DATE OF SERVICE:

- [REDACTED] +168

RESPONSIBLE STAFF SURGEON:

FELLOW OR CONSULTANT:

HOUSESTAFF SURGEON:

ASSISTANT:

PREOPERATIVE DIAGNOSES:

Metastatic right-sided colon cancer with clear evidence of stage IV disease upon abdominal exploration and dissection for malignant bowel obstruction in [REDACTED] ~+0

POSTOPERATIVE DIAGNOSES:

Metastatic right-sided colon cancer with clear evidence of stage IV disease upon abdominal exploration and dissection for malignant bowel obstruction in [REDACTED] ~+0

PROCEDURES:

[page 10 of 25]
1. Exploratory laparotomy, extensive lysis of adhesions, lasting approximately 2 hours.
2. Resection of mesenteric nodule, without clear evidence of malignancy.
3. Hepatic artery lymph node biopsy.
4. High-dose intraperitoneal chemotherapy with circulating 2 mg per mL of mitomycin.
5. Abdominal closure.

ANESTHESIA:

General.

SPECIMEN:

1. Omental biopsy.
2. Hepatic artery lymph node

INTRAOPERATIVE FINDINGS:

No clear evidence of residual stage IV disease upon abdominal exploration. Right upper, right lower, left upper, left lower quadrants, and pelvis were carefully explored. As a result, the CCI on this patient has to be zero. An omental nodule was biopsied, without evidence of malignancy on frozen section. An enlarged hepatic soft lymph node approximately 3 cm was sent for permanent. The extensive adhesions had to be taken down in the abdomen, lasting well over 2 hours.

INDICATIONS FOR PROCEDURE:

The patient is a very pleasant 69-year-old African American female whom I had seen back in [REDACTED] in an intraoperative ~+0 consultation. At that point, [REDACTED], our acute care surgeon, took the patient to the operating room for bowel obstruction, secondary to obstructing right-sided colonic malignancy. During exploration, there was also evidence of ovarian disease and some concerns about primary ovarian cancer. However, final pathology revealed evidence of colon cancer. The patient had clear evidence of widespread small nodules throughout the abdomen that I have personally observed. She underwent appropriate postoperative chemotherapy by [REDACTED], followed by recommendations for abdominal exploration and Debulking with HIPEC. The patient signed informed consent prior to proceeding with surgery.

QUALITY STATEMENTS:

1. Appropriate timeout was called prior to initiating any surgeries.
2. Bilateral lower extremity foot pumps were used to decrease the chance of blood clots.
3. Upper and lower body warmer used to decrease the chance of hypothermia.

[page 11 of 25]
4. Cefoxitin 2 g cefoxitin were given as a preoperative antibiotic to decrease the chance of wound infection.
5. Subcutaneous heparin 5000 mg was given to decrease the chance of blood clots.

DESCRIPTION OF THE PROCEDURE:

The patient was taken to the operating room on the date mentioned above and placed on the operating table in supine position. General endotracheal anesthesia was induced without difficulty. The abdomen was prepped and draped onto a sterile field in standard fashion. After placement of NG tube and Foley catheter, peripheral IVs, as well as changing the body positioning from supine to a lithotomy using the yellow fins, as well as palpating the extremities.

Next, a midline incision was made and the abdomen. It was pretty obvious that there are multiple loops of small bowel matted to each other all the way down to the pelvis. In addition to evidence of transverse colon matted to the abdominal wall. Extensive lysis of adhesions, lasting over 2 hours, was started. First, the colon was taken off the anterior abdominal wall, after placement of a Bookwalter, followed by extensive lysis of adhesion involving the small bowel, mostly in the pelvis and right lower quadrant. This lasted over 2 hours. By the time we were done, there were several superficial and one deeper serosal injuries, which were fixed with 3-0 silk sutures.

The small bowel was run from ligament of Treitz all the way down to the terminal ileum and transverse colon anastomosis. The liver was palpated, anterior and posterior surfaces bilaterally. The left upper quadrant had no evidence of disease around the stomach or around the spleen. The lesser sac was entered by dissecting the omentum off the transverse colon without identification of any evidence of disease. The left lower quadrant and pelvis were clearly palpated. Initially, we felt some nodularity in the pelvis, however, after bringing all the small bowel out the pelvis, this was evidence of some clips placed during previous surgery.

The upper and lower abdomen were cannulated. The inflow catheters were placed in the upper abdomen and outflow catheters as a full suction plastic device in the lower. A closed circuit was established. The fluid was perfused for approximately 30 minutes to reach a temperature of 39.

At this point, a total of 50 mg of mitomycin was injected in 2 separate portions. The maximum was 750 mL per minute. The tissue temperature was 39.2 and washout volume of 6000. The

[page 12 of 25]
[REDACTED]

[REDACTED]

perfusion lasted over an hour, followed by a wash with 6 liter of fluid, as mentioned above.

Following this, the abdominal wall nylon sutures were taken out, followed by a temperature probe and abdominal cannulas. The abdomen was irrigated. The residual fluid was removed. The small bowel was run from the ligament of Treitz all the way down to the transverse colon anastomosis, without clear evidence of additional injuries that needed to be fixed. The abdomen was closed with interrupted #1 Maxon sutures and application of skin staplers. The patient was awakened from general anesthesia without difficulty. Final sponge and instrument counts were correct.

I was attending physician, was present for the entire case, from skin incision to closure.

[REDACTED]

Revision History [REDACTED]

Note Routing History

Routing history could not be found for this note. This is because the note has never been routed or because it was routed prior to the date on which the required Chart Review routing print group setup was completed [REDACTED]

[REDACTED]

[page 13 of 25]
Orders Only

Provider: System, Provider Not In

Department: Unassigned Department Dept Phone: Encounter #: ■

Results Incoming

+14

Narrative

SPECIMEN INFORMATION

Specimen Identifier + Block: ■

Specimen Type: Large intestine, cecum and ascending colon, right hemicolectomy

Date of Original Collection: ■ +0

Date of Laboratory Receipt: ■ +3

Originating Institution: ■

Tissue Processing: Formalin fixed, paraffin embedded

Specimen Assessment: Tumor cells present, adequate for evaluation

RESULTS

MICROSATELLITE INSTABILITY PCR ANALYSIS

MSI RESULT: MSS - Stable Microsatellites

Individual Alleles: BAT 25: Stable

BAT26: Stable MONO27: Stable NR21: Stable NR24: Stable

INTERPRETATION

There is no evidence of microsatellite instability in the tested specimen.

This finding indicates a low probability of underlying hereditary non-polyposis colorectal carcinoma syndrome (HNPCC, a.k.a. Lynch Syndrome).

However, up to 5% of patients with HNPCC do not show evidence of microsatellite instability by MSI testing. Correlation with immunohistochemical findings, clinical features and family history is necessary for complete interpretation of these findings. Separately performed immunohistochemical studies demonstrated no loss of expression in tumor nuclei of the mismatch repair proteins MLH1, MSH2, MSH6, and PMS2 (see ■). Additionally, separately performed mutational studies show an APC mutation (see ■). Genetic counseling may be considered to aid in the interpretation of this result and could be considered in the setting of family or personal history of multiple malignancies.

Methods and Assay Limitations

Preanalytical Processing: H+E stained paraffin sections were examined by a board-certified anatomic pathologist for testing suitability. Non-tumor tissue was isolated by microscope assisted microdissection followed by cell lysis and DNA extraction. Previously microdissected, lysed and extracted

[page 14 of 25]
regions of tumor were utilized.

MSI Analysis: Extracted DNA from both tumor and non-tumor regions was separately amplified using multiplex PCR targeted to five mononucleotide repeat loci, followed by capillary electrophoresis and analysis of amplicon size.

Clinical History:
Request for MSI testing.

Reviewed and Interpreted by:

[REDACTED]

"I certify that (1) all services on this form were rendered and are hereby approved for billing, (2) all specimens/slides have been examined/reviewed, (3) the medical record has been documented for these services, and (4) the rendering of the services and the documentation in the medical record are in accordance with [REDACTED] guidelines."

This test was developed in and its performance characteristics determined by the [REDACTED]

[REDACTED] The procedures and reagents used in immunohistochemical and molecular diagnostic tests have been validated by evaluation of normal control patients and positive controls. This testing has not been cleared by the United States Food and Drug Administration (FDA). However, the FDA has determined that such clearance or approval is not required for clinical implementation. Test results have been shown to be clinically useful. The [REDACTED]

[REDACTED] (CLIA-88) to perform high complexity clinical laboratory testing.

[REDACTED]

Ordered by an unspecified provider

[REDACTED]

Ordering User

Authorizing Provider

[REDACTED]

System, Provider Not In

PCP

[REDACTED]

[REDACTED]

[REDACTED]

Specimen ID:

[REDACTED]

Lab

DEPARTMENT

[REDACTED]

[REDACTED]

[page 15 of 25]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[page 16 of 25]
Orders Only

Provider: System, Provider Not In

Department: Unassigned Department Dept Phone: Encounter #:

+14 Results Incoming

Narrative

SPECIMEN INFORMATION

Specimen Identifier + Block:

Specimen Type: Large intestine, cecum and ascending colon, right hemicolectomy

Date of Original Collection: +0

Date of Laboratory Receipt: +3

Originating Institution:

Tissue Processing: Formalin fixed, paraffin embedded

Specimen Assessment: Tumor cells present, adequate for evaluation

RESULTS:

MULTIPLEX MUTATION ANALYSIS by Targeted Next-Generation Sequencing

Mutations Identified (SEE INTERPRETATION)

Gene Predicted Protein Changes Nucleotide Change

APC p.R1450* c.4348C>T

No additional significant mutations were identified in KRAS, BRAF, NRAS, PIK3CA, or the remainder of the panel (see Assay Methodology section for panel contents).

INTERPRETATION

Mutations were identified in this sample:

1. APC p.R1450* c.4348C>T

There is evidence of a point mutation in APC resulting in an anticipated premature stop codon at position 1450 (p.R1450*). In the Catalogue of Somatic Mutations in Cancer, this mutation is among the most commonly described missense mutations, reported 226 times, predominantly in colorectal carcinoma (). Sporadic colorectal adenomas and -393 carcinomas commonly contain somatic mutations that inactivate APC resulting in unchecked signaling through the B-catenin/Wnt pathway. The prognostic or predictive significance of APC mutations in colorectal carcinoma is not well understood. Analysis of APC is based on reference sequence NM_000038.5.

METHODS AND ASSAY LIMITATIONS:

[page 17 of 25]
Mutation Analysis

Preanalytical Processing: H+E-stained paraffin sections were examined by a board-certified anatomic pathologist for testing suitability. Tumor cells were isolated by microscope assisted microdissection followed by tumor cell lysis and DNA extraction.

Solid Tumor Sequencing Panel

Sequence analysis of selected coding regions of 26 genes involved with solid tumors (AKT1, ALK, APC, BRAF, CDH1, CTNNB1, EGFR, ERBB2, FBXW7, FGFR2, FOXL2, GNAQ, GNAS, KIT, KRAS, MAP2K1, MET, MSH6, NRAS, PDGFRA, PIK3CA, PTEN, SMAD4, SRC, STK11, TP53) was carried out using the TruSight Tumor sequencing panel (Illumina, Inc.). Custom bioinformatic analysis developed at [REDACTED] was applied to map targeted regions, and identify variants and assay artifacts. Specific targeted regions analyzed are available from [REDACTED] upon request. Variants in intronic regions, or alterations anticipated to produce no amino acid change are not reported.

Assay Limitations:

This assay does not detect all types of mutations. For example, chromosomal translocations, gene fusions, and copy number alterations are not detected.

Insertions and deletions larger than 40 base pairs may not be detected. The analytic sensitivity for mutations in the genes listed above at 500x minimum coverage of each region is 5% variant allele frequency. Unless otherwise specified, all reported regions met the minimum criteria of 500x coverage. Although microdissection is employed, mutations present at a level below the analytic sensitivity may not be detected by this assay. This assay is not designed for the detection of germline alterations.

Clinical History:

Request for Multiplex Tumor Panel.

Reviewed and Interpreted by:

[REDACTED]

[REDACTED]

[REDACTED]

[page 18 of 25]
accredited by the College of American Pathologists (CAP) and certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) to perform high complexity clinical laboratory testing.

Comments

Ordered by an unspecified provider

Provider Information

Ordering User

Authorizing Provider

Results Incoming

System, Provider Not In

Specimen Information

Specimen ID

Lab Information

Lab

E

[page 19 of 25]
Radiology CT Scan

RADIOLOGY REPORT

Visit #: [REDACTED]

HAR [REDACTED]

Patient Information

Signs & Symptoms: Hx of stage IV colon cancer s/p resection
History: Adenocarcinoma of cecum (HC code)

Order InformationExam(s): **CT CHEST/ABD/PELV W CONTRAST**

Accession #: [REDACTED] -

Exam Date: [REDACTED] +51

Final

COMPUTED TOMOGRAPHY CHEST, ABDOMEN AND PELVIS WITH INTRAVENOUS CONTRAST

DATE OF EXAM: [REDACTED] +52

COMPARISON: CT CHEST [REDACTED], CT ABD/PELV [REDACTED].
-6 -7

INDICATION: New baseline Hx of stage IV colon cancer s/p resection

TECHNIQUE: Contrast enhanced chest, abdomen and pelvis CT performed during the injection of 92 ml of Isovue 370.

FINDINGS:

Thyroid: Multiple subcentimeter thyroid nodules.

Thoracic inlet: Supraclavicular lymph nodes are not Changed in size.

Heart and great vessels: Heart is normal size without pericardial effusion. Great vessels are normal caliber.

Mediastinum and hila: No mediastinal or hilar lymphadenopathy.

Lungs and pleura: Thrombus seen within the basal segmental arteries extending off of the right pulmonary artery [REDACTED]. There is no evidence of right heart strain.

Chest and axilla: Right-sided chest port. No axillary lymphadenopathy.

[page 20 of 25]
ABDOMEN AND PELVIS:

Liver and hepatic vasculature: The hepatic vasculature is patent. No focal hepatic masses. No hepatomegaly.

Gallbladder and bile ducts: No cholelithiasis or gallbladder wall thickening.

Spleen: No splenomegaly.

Pancreas: Pancreas is normal without main pancreatic ductal dilation.

Adrenals: Adrenal glands are normal.

Kidneys, ureters and bladder: No nephrolithiasis. Subcentimeter hypodensities throughout the left kidney are too small to characterize.

Retroperitoneum and aorta: No retroperitoneal lymphadenopathy. Mild amount of non-circumferential aortic calcification.

GI tract, mesentery and peritoneum: Status post right hemicolectomy. There is no bowel thickening around the colonic anastomosis within the right abdominal quadrant (). There is a mild amount of fat stranding and punctate nodules () within the mesentery. Diverticulosis without diverticulitis.

Uterus and adnexa: The uterus is surgically absent. No adnexal masses.

Bones and soft tissues: Mild degenerative changes throughout the visualized portion of the spine.

IMPRESSION:

1. Right lower lobe segmental pulmonary embolus. No evidence of right heart strain.
2. Status post right colectomy with no definitive evidence of local recurrence. Of note, punctate nodules within the mesentery are non-specific and should be reassessed on follow-up imaging.
3. No evidence of distant metastatic disease.

+52

() discussed findings with () by telephone on () Critical readback was performed.

If you are a health care provider and have any questions regarding this or any other Thoracic Radiology report please call () . ()

If you are a patient and have questions about your report please contact your health care provider.

Reading Physician ()

Reviewed and Interpreted By: ()

[page 21 of 25]
RADIOLOGY REPORT

Patient Information

Age/Sex

Birth Date

Visit #

HAR

Signs & Symptoms: known colon cancer

History: Malignant neoplasm of sigmoid colon (HC code)

Order Information

Exam(s): CT CHEST/ABD/PELV W CONTRAST

Accession #

Exam Date

Ord Provide

+122

Final

EXAMINATION: CT OF THE CHEST, ABDOMEN, AND PELVIS WITH IV CONTRAST

INDICATION: Colon cancer. Evaluate for progression while on chemo

TECHNIQUE: Transaxial images of the chest, abdomen, and pelvis were obtained from the apex of the lungs to the ischial tuberosity according to routine chest, abdomen, and pelvis protocol, following the uneventful administration of intravenous contrast material, Isovue 370, 89 ml.

COMPARISON: Comparison is made to the prior CT dated +51

FINDINGS:

CHEST:

Thyroid: Stable small thyroid nodules.

Heart and pericardium: The heart is normal in size. Coronary artery atherosclerotic calcifications are not seen. No pericardial effusion.

Mediastinum and hila: Mild aortic atherosclerosis. The great vessels and airways are otherwise normal. No significant mediastinal or hilar lymphadenopathy.

Lungs and pleura: Scattered subpleural nodules measuring up to 0.4 cm in diameter, as seen for instance in the lingula in series 3 image 54, are stable from before. No pleural effusion.

Chest wall: The distal tip of a right chest wall Infuse-a-Port is in the downstream SVC. No significant supraclavicular or axillary lymphadenopathy.

[page 22 of 25]
ABDOMEN AND PELVIS:

Liver: Stable tiny hypoattenuating segmental lesion in series [REDACTED] too small to further characterize.

Bile ducts: Nondilated.

Gallbladder: Normal.

Pancreas: Stable mild atrophy with ductal prominence but without frank duct dilation and without pancreatic mass seen.

Spleen: Normal.

Adrenals: Normal.

Kidneys/Ureters/Urinary Bladder: Small hypodense renal lesions probably represent cysts but are too small to further characterize. Normal urinary bladder.

Reproductive organs: Hysterectomy changes.

GI tract: No evidence of bowel obstruction. Colonic diverticula without evidence of diverticulitis. Stable changes of right hemicolectomy with jejunocolostomy. The peritoneal disease that was previously present in the left mid to low abdomen adjacent to the redundant transverse colon (e.g., 2.3 cm nodule in series 3 image 147 of the reference CT) is not seen today. No new peritoneal disease is seen. No pneumoperitoneum. No ascites.

Lymph nodes: No adenopathy.

Vasculature: The abdominal aorta and IVC are unremarkable.

Superficial soft tissues: Nodules in the subcutaneous fat of the anterior abdominal wall presumably from medication injection. Anterior abdominal wall scar.

Bones: No suspicious lesions. Degenerative changes are seen in the spine.

IMPRESSION: Resolution of previously present peritoneal metastasis, reflecting treatment response. No new metastatic disease is seen.

Patients: The medical language used in this report is intended for medical professionals. If you have any questions regarding this radiology report, please ask your primary care providers.

Reading Physician: [REDACTED]
Reviewed and Inter [REDACTED]

[page 23 of 25]
RADIOLOGY REPORT

Patient Information

Age/Sex
Birth Date

Visit #:

HAR

Signs & Symptoms:
History: Adenocarcinoma of cecum (HC code)

Order Information

Exam(s): CT CHEST/ABD/PELV W CONTRAST

Exam Date:

Ord Provide

+612

Final

COMPUTED TOMOGRAPHY CHEST, ABDOMEN , AND PELVIS WITH INTRAVENOUS CONTRAST:

+612

TECHNIQUE: Contrast enhanced chest, abdomen, and pelvis CT performed during the injection of 80 ml of Isovue 370.

HISTORY PER ORDERING PHYSICIAN: "surveillance post treatment of colon adenoca"

COMPARISON: CT chest/abdomen/pelvis +476

FINDINGS:

CHEST:

Thyroid: Multiple thyroid nodules redemonstrated, the largest in the left anterior lobe measures approximately 0.7 cm, stable.

Thoracic inlet: Increase in size of enlarged lymph node subjacent to the left pectoralis minor muscle, 1.0 cm in short axis. Other scattered prominent lymph nodes along the thoracic inlet and axilla are unchanged. No vascular abnormality.

Heart and great vessels: Right chest port central venous catheter tip is at the lower SVC. No cardiac abnormality. Normal pericardium. No aortic or main pulmonary ectasia. The great vessels demonstrate typical branching anatomy.

[page 24 of 25]
Mediastinum and hila: No lymphadenopathy. Normal esophagus and trachea.

Lungs and pleura: Normal lung expansion. Interval development of multiple pulmonary nodules the largest as follows: Right upper lobe, 0.7 cm [REDACTED] right upper lobe, 0.4 cm [REDACTED] and left lower lobe, 0.6 cm [REDACTED]. No consolidation. Anterior-left upper lobe and bibasilar scarring/atelectasis is unchanged. Central airways are clear of secretions. No pleural effusion or pneumothorax.

Breast and axilla: No nodules/masses. Unchanged prominent axillary lymph nodes without lymphadenopathy by size criteria.

ABDOMEN/PELVIS:

Liver: The liver appears normal in size, shape, and attenuation. A hypoattenuating, thin-walled lesion in hepatic segment seven is unchanged, most probably a simple cyst [REDACTED]. Patent portal veins.

Bile ducts: No intra- or extra-hepatic dilation.

Gallbladder: Decompression limits evaluation. No radiopaque gallstones or focal wall thickening.

Pancreas: Mild fatty atrophy.

Spleen: No splenomegaly. Unchanged anterior splenule.

Adrenals: Nodular appearance of the left adrenal gland is not significant change.

Kidneys/Ureters/Urinary Bladder: Kidneys and ureters appear normal. No hydronephrosis or hydroureter. No nephroureterolithiasis. Urinary bladder is thin walled and distended.

Reproductive organs: Uterus is surgically absent.

GI tract/Mesentery: Enteric contrast fills segments of small and bowel. Right hemicolectomy with ileocolic anastomosis without evidence of anastomotic failure. There are surgical clips throughout the pelvis and along the sigmoid colon. Increased size of mass in the anterior perirectal space that appears continuous with the anterior rectal wall, now measuring 3.7 x 2.1 cm, previously approximately 3.1 x 1.4 cm [REDACTED]. There is no dilation, focal stenosis, or wall thickening. No evidence of obstruction. Physiologic quantity and distribution of bowel gas and colonic stool. Appendix not identified. No pericecal inflammation.

Peritoneum: No ascites. No pneumoperitoneum.

Retroperitoneum: No retroperitoneal lymphadenopathy by size criteria.

Vasculature: No AAA or focal stenosis. The IVC appears unremarkable.

Bones and soft tissue: No new focal osseous lesion. Well-circumscribed sclerotic lesion in the right humeral head has benign features and is unchanged. Multilevel degenerative changes of the visualized spine as well as bilateral femoroacetabular and glenohumeral osteoarthritis, unchanged. Anterior abdominal scar reflects prior open abdominal surgery.

IMPRESSION:

1. Interval development of multiple pulmonary nodules, as detailed, concerning for metastatic disease.
2. Mass in the anterior perirectal space appears continuous with the anterior rectal wall and measures up to 3.7 cm. Concerning for disease recurrence.
3. Increase in size of left chest wall lymph nodes adjacent to the pectoralis minor muscle.

[page 25 of 25]
If you are a patient and have questions about your report please contact your health care provider.

Source: NCI Genomic Data Commons file f89a9d9e-2757-4974-8e75-6ce225c81f23 (ER0425 ER-B0GI Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).